Gene-level copy-number profile of tumor specimen TCGA-06-0192-01B from TCGA case TCGA-06-0192, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.2 years (21,243 days).
Specimen TCGA-06-0192-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.dd3ddbb2-2e57-4748-a8c1-fa14c6d89d89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0192-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/93d39f8d-df71-4524-a831-e5e7af707496

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 6,621; copy number 2: 45,595; copy number 3: 7,453; copy number 4: 1; copy number 5: 2; copy number 6: 22; copy number 8: 25; copy number 10: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0192-01B-01D-0333-01): tumor purity 0.57, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,106,543–24,905,735, 71 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 79 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:31,997,376–36,244,514, 22 genes, copy number 6 (within-gene range 2–6): LINC02506, AC097654.1, LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P, ARAP2, AC098827.1.
- chr4:51,843,000–54,976,371, 55 genes, copy number 8–10: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3.
- chr6:117,299,364–117,301,758, 2 genes, copy number 5: RN7SKP18, RN7SKP51.

Autosomal genes at a single copy (total copy number 1): 4,234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
